Somatic mutation profile of tumor specimen TARGET-20-PARWWW-03A (aliquot TARGET-20-PARWWW-03A-01D) from TARGET case TARGET-20-PARWWW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.6 years (6,079 days).
Specimen TARGET-20-PARWWW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1e7fbba-9e48-476c-b86f-a35eb77a1eeb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARWWW-14A (Bone Marrow Normal), aliquot TARGET-20-PARWWW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba220592-cc6e-4534-afa1-2b23bbc8128f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, In Frame Del 1, Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1251_1257delinsCTCT p.Y418_D419delinsS | In Frame Del (DEL) | VAF 14/118 reads (12%) | catalogued as COSV55401618; called by pindel, varscan2*
- TYK2 | c.2299C>A p.L767I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99314396; called by muse, mutect2
- ASXL2 | c.1331_1335del p.K444Rfs*3 | Frame Shift Del (DEL) | VAF 39/143 reads (27%) | called by mutect2, pindel, varscan2
- PHF6 | c.36_37insTCCTA p.R13Sfs*2 | Frame Shift Ins (INS) | VAF 16/31 reads (52%) | called by mutect2, pindel, varscan2
